Somatic mutation profile of tumor specimen HCM-CSHL-0240-C18-01A (aliquot HCM-CSHL-0240-C18-01A-11D-A78J-36) from HCMI case HCM-CSHL-0240-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 81.9 years (29,899 days).
Specimen HCM-CSHL-0240-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4697fd3b-88d7-4e0b-ac24-1946b4124203.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0240-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0240-C18-11A-11D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e447a1e5-7b4a-4f10-b7b7-71522fa2a537

The open-access MAF lists 2,563 somatic variants for this specimen: 1,717 protein-altering or splice-affecting, 518 silent, 328 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,183, Silent 518, Frame Shift Del 339, Intron 156, Frame Shift Ins 68, Nonsense Mutation 57, 3'UTR 56, 5'UTR 38, 5'Flank 33, Splice Region 32, RNA 27, Splice Site 20.

Variants (750 of 2,563; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX4 | c.398del p.P133Rfs*48 | Frame Shift Del (DEL) | VAF 44/169 reads (26%) | catalogued as rs1085307637, COSV61327307; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRPF1 | c.2794del p.Q932Sfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs762904815, COSV57403691; ClinVar: pathogenic; called by mutect2, varscan2
- DDX3X | c.1123C>T p.R375C (on ENST00000399959; = p.R376C on NM_001356.5) | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs796052231, CM158018, COSV67863865, COSV67864092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.136del p.Q46Sfs*146 | Frame Shift Del (DEL) | VAF 34/184 reads (18%) | catalogued as rs587783629; ClinVar: pathogenic; called by pindel, varscan2
- FOXG1 | c.460dup p.E154Gfs*301 | Frame Shift Ins (INS) | VAF 30/132 reads (23%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, varscan2
- GLDC | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs386833587, CM042354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 83/361 reads (23%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KIF1A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 106/451 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045655, COSV57486594; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 36/170 reads (21%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LBR | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754049402; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 28/104 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, varscan2
- MYH7 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 138/534 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1224554825, CM994128, COSV62520721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 62/495 reads (13%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- NEB | c.13705C>T p.R4569* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs754369875, CM1213409, COSV50859766; ClinVar: pathogenic; called by muse, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 42/209 reads (20%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 50/306 reads (16%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 72/354 reads (20%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPV4 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 200/718 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912633, CM083203, COSV55680649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 153/619 reads (25%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- ABCA3 | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs762690602, COSV100068696; called by muse, mutect2, varscan2
- ABCC6 | c.3320T>C p.V1107A | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780276741; called by muse, mutect2, varscan2
- ABCF3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs755216413, COSV53047219; called by muse, mutect2, varscan2
- ABCG4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs758347342; called by muse, mutect2, varscan2
- ABLIM3 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs904630965; called by muse, mutect2, varscan2
- ACLY | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1426806782; called by muse, mutect2, varscan2
- ACTA1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1353303107, COSV64204113; called by muse, mutect2, varscan2
- ACTL7A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as rs367785686; called by muse, mutect2, varscan2
- ACTN2 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs551141480, COSV63972194, COSV63975552; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTN2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV63978276; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 50/102 reads (49%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 30/169 reads (18%) | catalogued as COSV100008254; called by muse, mutect2, varscan2
- ADAMTS7 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66309539; called by muse, mutect2, varscan2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 73/288 reads (25%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADGRB2 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768585899; called by muse, mutect2, varscan2
- ADGRD2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV58340971; called by muse, mutect2
- ADGRE5 | c.1139G>A p.R380H (on ENST00000242786 / NM_078481.4; = p.R287H on NM_001784.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs149991001; called by muse, mutect2, varscan2
- ADGRF3 | c.2269G>A p.V757I (on ENST00000311519 / NM_001145168.1; = p.V558I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/483 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs757696637; called by muse, mutect2, varscan2
- ADGRL2 | c.3545G>A p.G1182D | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV99589248; called by muse, varscan2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 25/106 reads (24%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 43/155 reads (28%) | catalogued as rs753451653, COSV100321078; called by muse, mutect2, varscan2
- AGAP3 | c.1136G>A p.G379D (on ENST00000622464; = p.G415D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752343058; called by muse, mutect2, varscan2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 59/277 reads (21%) | catalogued as rs747733044, COSV59935415; called by mutect2, pindel, varscan2
- AGO2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as rs912917128; called by muse, mutect2, varscan2
- AGT | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64183981, COSV64184605; called by muse, mutect2
- AHNAK2 | c.9795del p.D3266Tfs*36 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs777248951, COSV60907891; called by mutect2, pindel, varscan2
- AHRR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775797513; called by muse, mutect2, varscan2
- AJM1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754098168; called by muse, varscan2
- AKAP17A | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs375125397, COSV100002218; called by muse, mutect2, varscan2
- AKAP3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs200377453, COSV57415556; called by muse, mutect2, varscan2
- AKAP6 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs141386857, COSV55214164; called by muse, mutect2, varscan2
- AKAP9 | c.6977C>T p.T2326M (on ENST00000359028; = p.T2302M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs368444006; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AKT1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs369698909; called by muse, mutect2, varscan2
- ALDH5A1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); catalogued as rs768533338; called by muse, mutect2, varscan2
- ALG11 | c.52del p.Y18Ifs*35 | Frame Shift Del (DEL) | VAF 67/318 reads (21%) | catalogued as COSV73000541; called by mutect2, pindel, varscan2
- ALG8 | c.206del p.P69Lfs*22 | Frame Shift Del (DEL) | VAF 53/230 reads (23%) | catalogued as CM098505; called by mutect2, pindel, varscan2
- ALKBH4 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs754692846; called by muse, mutect2, varscan2
- AMER1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57656670; called by muse, mutect2, varscan2
- AMIGO1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100881075; called by muse, mutect2, varscan2
- ANK3 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753344992, COSV104383739; called by muse, mutect2, varscan2
- ANKRD11 | c.6005C>A p.S2002Y | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99039934; called by muse, mutect2, varscan2
- ANKRD16 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs200993355, COSV51947535; called by muse, mutect2, varscan2
- ANKRD34A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1553761404, COSV60160896; called by muse, mutect2, varscan2
- ANKRD34A | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs782545703, COSV60161202; called by muse, mutect2, varscan2
- ANKRD46 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs376278571; called by muse, varscan2
- ANKRD63 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs1464803596; called by muse, mutect2, varscan2
- ANO8 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs757084785, COSV50192062; called by muse, mutect2, varscan2
- AP5B1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs372030130; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs546686089; called by mutect2, varscan2
- APOL3 | c.886C>T p.R296C (on ENST00000349314 / NM_145640.2; = p.R225C on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs141623013; called by muse, mutect2, varscan2
- ARHGAP23 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs1455090989; called by muse, mutect2, varscan2
- ARHGAP23 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs775996184; called by muse, varscan2
- ARHGAP26 | c.1709C>G p.T570S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV50826879; called by muse, varscan2
- ARHGAP33 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs773138268; called by muse, mutect2, varscan2
- ARHGAP33 | c.3254dup p.E1086Rfs*34 | Frame Shift Ins (INS) | VAF 26/177 reads (15%) | catalogued as rs762833509; called by mutect2, varscan2
- ARHGAP35 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs776102282, COSV68335942; called by muse, mutect2, varscan2
- ARHGAP45 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs761730903, COSV57431886; called by muse, mutect2, varscan2
- ARHGEF3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950370717; called by muse, mutect2, varscan2
- ARHGEF33 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.228); catalogued as rs554200497; called by muse, mutect2, varscan2
- ARHGEF40 | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745722398; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 25/131 reads (19%) | catalogued as rs776520069; called by mutect2, varscan2
- ARL13B | c.932del p.N311Ifs*6 (on ENST00000394222 / NM_001174150.2; = p.N204Ifs*6 on NM_144996.4) | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs750642821; called by mutect2, varscan2
- ARMCX6 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 73/495 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1180836922; called by muse, mutect2, varscan2
- ARPP21 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs762995319; called by muse, mutect2, varscan2
- ASB13 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1320507093; called by muse, mutect2, varscan2
- ASB18 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1366619475; called by muse, mutect2
- ASB2 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60112053; called by muse, mutect2, varscan2
- ASCL4 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60816741; called by muse, mutect2, varscan2
- ASIC4 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV61731524; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 67/343 reads (20%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ASXL1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 50/572 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs899345535; called by muse, mutect2
- ATP10A | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs1372051472; called by muse, mutect2, varscan2
- ATP13A1 | c.907-6G>A | Splice Region (SNP) | VAF 72/262 reads (27%) | catalogued as rs767187901; called by muse, mutect2, varscan2
- ATP6AP1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs782330877, COSV100870716; called by muse, mutect2
- ATRX | c.4795G>A p.G1599S | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64881575; called by muse, mutect2, varscan2
- AXL | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as rs775611992; called by muse, varscan2
- B3GNT7 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767791399, COSV55006560; called by muse, mutect2
- B3GNT8 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.84); catalogued as rs367663254; called by muse, mutect2, varscan2
- B3GNT9 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV54625749; called by muse, mutect2, varscan2
- B4GALT7 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs764639019, COSV50352584; called by muse, varscan2
- BAHCC1 | c.2706del p.M903Cfs*71 | Frame Shift Del (DEL) | VAF 40/168 reads (24%) | catalogued as COSV100311192; called by mutect2, pindel, varscan2
- BAP1 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 54/627 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.198); catalogued as COSV56240578; called by muse, mutect2
- BAZ2B | c.2166_2168del p.S723del | In Frame Del (DEL) | VAF 32/135 reads (24%) | catalogued as rs752085908; called by pindel, varscan2
- BCAS3 | c.1888C>T p.R630* (on ENST00000390652 / NM_001353144.2; = p.R615* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 49/224 reads (22%) | catalogued as rs1416992531; called by muse, mutect2, varscan2
- BCL11B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1457974153; called by muse, varscan2
- BCORL1 | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146180952; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 49/180 reads (27%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BICDL2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs764803591, COSV54156544; called by muse, mutect2
- BID | c.434G>A p.R145H (on ENST00000317361 / NM_197966.2; = p.R99H on NM_001196.4) | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370897535, COSV58008766; called by muse, mutect2, varscan2
- BIRC6 | c.8659G>A p.V2887M | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs755972507; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs1319474089; called by muse, mutect2
- BMX | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564274; called by muse, mutect2, varscan2
- BNC2 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 139/588 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.202); catalogued as rs1488921825; called by muse, mutect2, varscan2
- BRD1 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768796290; called by muse, mutect2
- BRPF1 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs753525669; called by muse, mutect2, varscan2
- BRPF1 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs768402081, COSV57407406; called by muse, mutect2, varscan2
- BRSK1 | c.347del p.G116Vfs*8 | Frame Shift Del (DEL) | VAF 33/169 reads (20%) | catalogued as rs776865070; called by mutect2, pindel, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 34/126 reads (27%) | catalogued as rs1558005082; called by mutect2, varscan2
- BTN2A1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); catalogued as COSV57005840; called by muse, varscan2
- C11orf42 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs781116265, COSV56410011; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 36/169 reads (21%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C17orf80 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs369548621; called by muse, mutect2, varscan2
- C1QTNF4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1372789544; called by muse, mutect2, varscan2
- C1QTNF9 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1419089027; called by muse, mutect2, varscan2
- C2 | c.2249dup p.L750Ffs*39 | Frame Shift Ins (INS) | VAF 85/443 reads (19%) | catalogued as rs774429190; called by mutect2, pindel, varscan2
- C4orf54 | c.990del p.G331Efs*45 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as rs1388862189; called by mutect2, pindel, varscan2
- C6 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1416773804, COSV54712077; called by muse, varscan2
- C8orf74 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1267914932, COSV58755007; called by muse, mutect2, varscan2
- CABIN1 | c.4109C>T p.T1370M | Missense Mutation (SNP) | VAF 128/538 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs761243312; called by muse, mutect2, varscan2
- CACNA1G | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61728654; called by muse, mutect2, varscan2
- CACNA1I | c.5744C>T p.S1915L | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as rs374151542; called by muse, mutect2, varscan2
- CACNA1S | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs776209588; called by muse, mutect2, varscan2
- CAMSAP3 | c.2266T>C p.S756P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as rs939761601; called by muse, mutect2, varscan2
- CASP8 | c.1181C>T p.P394L (on ENST00000432109 / NM_033355.3; = p.P411L on NM_001228.4) | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51846287, COSV51861191; called by muse, mutect2, varscan2
- CASS4 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371811746; called by muse, mutect2, varscan2
- CASZ1 | c.5116G>A p.D1706N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.034); catalogued as rs760139587; called by muse, mutect2, varscan2
- CBX2 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.457); catalogued as COSV53969489; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | catalogued as rs780649799; called by mutect2, varscan2
- CCAR2 | c.1513dup p.L505Pfs*32 | Frame Shift Ins (INS) | VAF 208/458 reads (45%) | catalogued as rs748274275; called by mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC166 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1554616846; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | catalogued as rs773752200; called by mutect2, varscan2
- CD1D | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 118/544 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV63808559, COSV63810154; called by muse, mutect2, varscan2
- CD276 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs184115783; called by muse, mutect2, varscan2
- CD36 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV59211374; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 68/225 reads (30%) | catalogued as rs781937995, COSV99163893; called by mutect2, varscan2
- CD86 | c.203T>C p.V68A (on ENST00000330540 / NM_175862.5; = p.V62A on NM_006889.4) | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100054135; called by muse, mutect2, varscan2
- CDC25B | c.721C>T p.R241W (on ENST00000245960 / NM_021873.3; = p.R227W on NM_004358.4) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs202222511; called by muse, mutect2, varscan2
- CDC40 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs760746039; called by muse, mutect2, varscan2
- CDC5L | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs145762260; called by muse, mutect2, varscan2
- CDH16 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 15/465 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1490162866, COSV55335435; called by muse, mutect2
- CDH18 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99934222; called by muse, mutect2, varscan2
- CDH22 | c.1176del p.E393Sfs*24 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as rs768497155, COSV64836926; called by mutect2, pindel
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 72/280 reads (26%) | catalogued as rs765496989; called by mutect2, varscan2
- CDX4 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100999149; called by muse, mutect2
- CDYL2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as rs1348845116; called by muse, mutect2
- CENPC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371671240, COSV56623034; called by muse, mutect2, varscan2
- CEP112 | c.1655del p.K552Rfs*27 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs754269394; called by mutect2, pindel
- CEP112 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs147020220, COSV67137724; called by muse, mutect2, varscan2
- CEP295 | c.1657dup p.T553Nfs*18 | Frame Shift Ins (INS) | VAF 40/136 reads (29%) | catalogued as rs749718914; called by mutect2, varscan2
- CEP97 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs889687328; called by muse, mutect2, varscan2
- CFAP46 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 73/435 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV63951418; called by muse, mutect2, varscan2
- CGAS | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs200213844; called by muse, mutect2, varscan2
- CHD5 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1162494442, COSV52418865; called by muse, mutect2, varscan2
- CHD5 | c.1659dup p.F554Lfs*2 | Frame Shift Ins (INS) | VAF 23/198 reads (12%) | catalogued as rs1419451052; called by mutect2, pindel, varscan2
- CHEK1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs1486238508; called by muse, mutect2, varscan2
- CHRD | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 130/528 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as rs781476129; called by muse, mutect2, varscan2
- CHST5 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1454993446, COSV100291890; called by muse, mutect2, varscan2
- CIT | c.4790C>T p.T1597M | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773121506; called by muse, mutect2, varscan2
- CLDN23 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331817599; called by muse, mutect2, varscan2
- CNEP1R1 | c.336+14del | Splice Region (DEL) | VAF 40/181 reads (22%) | catalogued as rs1006253245; called by mutect2, pindel, varscan2
- CNGB1 | c.2351G>A p.S784N | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1460002577, COSV51900217; called by muse, mutect2
- CNOT4 | c.2054C>A p.S685Y (on ENST00000541284 / NM_001190850.1; = p.S611Y on NM_013316.4) | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs959505788; called by muse, mutect2, varscan2
- CNTFR | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs776532201, COSV100667623; called by muse, varscan2
- CNTNAP2 | c.133del p.H45Mfs*21 | Frame Shift Del (DEL) | VAF 40/424 reads (9%) | catalogued as COSV62156372; called by mutect2, pindel
- CNTNAP5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752392550, COSV101443557; called by muse, mutect2, varscan2
- COL11A2 | c.2483G>A p.R828Q (on ENST00000341947 / NM_080680.3; = p.R721Q on NM_080679.2) | Missense Mutation (SNP) | VAF 117/468 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs765292733, COSV100553921; called by muse, mutect2, varscan2
- COL18A1 | c.5009G>A p.R1670H (on ENST00000359759 / NM_130444.3; = p.R1435H on NM_030582.4) | Missense Mutation (SNP) | VAF 117/441 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs757116735, COSV60589336; called by muse, mutect2, varscan2
- COL1A2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1299614964; called by muse, mutect2, varscan2
- COL20A1 | c.3660del p.M1221Cfs*? | Frame Shift Del (DEL) | VAF 62/207 reads (30%) | catalogued as COSV100491399; called by mutect2, pindel, varscan2
- COPA | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs746722049; called by muse, mutect2, varscan2
- COQ6 | c.783G>A p.P261= | Splice Region (SNP) | VAF 90/492 reads (18%) | catalogued as rs199768730; called by muse, mutect2, varscan2
- CORIN | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs760929855; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 74/295 reads (25%) | catalogued as rs750161916; called by mutect2, varscan2
- CPLANE1 | c.257C>T p.A86V (on ENST00000425232; = p.A158V on NM_023073.3) | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as rs751087543; called by muse, mutect2, varscan2
- CPNE2 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs761049290; called by muse, mutect2, varscan2
- CPSF3 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV53012335; called by muse, mutect2, varscan2
- CRACD | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.114); catalogued as COSV99950244; called by muse, varscan2
- CRACD | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749775575; called by muse, varscan2
- CRB2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753791463, COSV63504880; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 61/272 reads (22%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CREM | c.859C>T p.R287C (on ENST00000429130; = p.R242C on NM_181571.3) | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760612758, COSV59770260; called by muse, mutect2, varscan2
- CSMD2 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs972030736, COSV53950724; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 81/167 reads (49%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTAG2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs782161068, COSV55994250; called by muse, mutect2, varscan2
- CTIF | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 111/476 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as rs999388776, COSV56480317; called by muse, mutect2, varscan2
- CUBN | c.5083C>T p.R1695C | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs770776726; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2
- CUX2 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55647884; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs772257590; called by mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 48/246 reads (20%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP2C19 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64907386; called by muse, mutect2, varscan2
- CYP2F1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs371341517; called by muse, mutect2, varscan2
- CYP4F22 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 159/617 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748463754; called by muse, mutect2, varscan2
- CYYR1 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs143400859; called by muse, mutect2, varscan2
- DAAM2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749423164, COSV51302512; called by muse, mutect2, varscan2
- DAXX | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.223); catalogued as COSV56466160; called by muse, mutect2, varscan2
- DCAF15 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs778950385, COSV54330638; called by muse, mutect2, varscan2
- DCAF5 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs750163325; called by muse, mutect2, varscan2
- DCBLD2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs562186974, COSV58793607; called by muse, mutect2, varscan2
- DCBLD2 | c.985A>C p.K329Q | Missense Mutation (SNP) | VAF 86/494 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58788923; called by mutect2, varscan2
- DCDC1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs931421406, COSV60833505; called by muse, mutect2, varscan2
- DDX51 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs780739881, COSV57957056; called by muse, mutect2, varscan2
- DGKH | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs868257718, COSV54927833; called by muse, varscan2
- DHDH | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs543413361; called by muse, mutect2, varscan2
- DHX37 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376228891; called by muse, mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 48/230 reads (21%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIP2A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168353430, COSV100595272; called by muse, mutect2, varscan2
- DIRAS3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63970685; called by muse, mutect2, varscan2
- DISP2 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.308); catalogued as COSV99139933; called by muse, mutect2
- DISP3 | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs374923562, COSV53824728; called by muse, mutect2, varscan2
- DISP3 | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53829192, COSV53830869; called by muse, mutect2, varscan2
- DKC1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs782121373; called by muse, mutect2, varscan2
- DLL1 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs944362947, COSV64536915; called by muse, mutect2, varscan2
- DLL3 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52696492; called by muse, mutect2
- DMAC2 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs782198516; called by muse, mutect2
- DNAAF3 | c.584G>A p.R195H (on ENST00000524407 / NM_001256715.2; = p.R242H on NM_178837.4) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1205307808; called by muse, mutect2, varscan2
- DNAH1 | c.6940C>T p.R2314C | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776689300, COSV70227864; called by muse, mutect2, varscan2
- DNAJC7 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs782177565; called by muse, mutect2, varscan2
- DNHD1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV54434867, COSV99600242; called by muse, mutect2, varscan2
- DNHD1 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs566226547, COSV54433194; called by muse, mutect2, varscan2
- DNM3 | c.2258C>T p.P753L (on ENST00000355305 / NM_001350206.2; = p.P747L on NM_015569.5) | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777632501, COSV62456380; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK5 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.553); catalogued as rs965183462, COSV52818039; called by muse, mutect2, varscan2
- DPM1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs750286694; called by muse, mutect2
- DRC7 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as rs768319912; called by muse, mutect2, varscan2
- DRICH1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 136/540 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.913); catalogued as rs775895089, COSV58503806; called by muse, mutect2, varscan2
- DRP2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371570852, COSV100871779; called by muse, mutect2, varscan2
- DSC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs777889677, COSV57145486, COSV57152642; called by muse, mutect2, varscan2
- DUS1L | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs145224994; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 34/131 reads (26%) | catalogued as rs746928635; called by pindel, varscan2
- DYNC1H1 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 135/487 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs781320162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF4 | c.1780C>T p.R594W (on ENST00000609451; = p.R590W on NM_001110514.1) | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs377714631; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 15/111 reads (14%) | catalogued as rs752987091; called by mutect2, varscan2
- EFCAB7 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs772663631; called by muse, varscan2
- EFCAB7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs775237667, COSV64314754; called by muse, varscan2
- EFHC1 | c.1918G>C p.G640R | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1006245677; called by muse, mutect2, varscan2
- EGFL6 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770186163; called by muse, mutect2, varscan2
- EGR2 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347453; called by muse, mutect2
- EHD1 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 146/588 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs757811551; called by muse, mutect2, varscan2
- EHD3 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771567803, COSV59029851; called by muse, mutect2, varscan2
- EIF4EBP2 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.596); catalogued as rs1392989013, COSV64667793; called by muse, mutect2, varscan2
- ELAVL2 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV56370644; called by muse, mutect2, varscan2
- ELOVL1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs753516275; called by muse, mutect2, varscan2
- EMC8 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53667789; called by muse, mutect2, varscan2
- EME1 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.517); catalogued as rs781277541, COSV99869573; called by muse, mutect2, varscan2
- ENGASE | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs754563242, COSV56136421; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 40/82 reads (49%) | catalogued as rs761717176; called by mutect2, varscan2
- EPHB6 | c.849dup p.R284Qfs*41 | Frame Shift Ins (INS) | VAF 17/115 reads (15%) | catalogued as rs145544148; called by mutect2, varscan2
- EPX | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs753502394; called by muse, mutect2, varscan2
- ERCC6 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 110/494 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs774463252; called by muse, mutect2, varscan2
- ERG | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as rs144012510; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 80/310 reads (26%) | catalogued as rs779855268; called by mutect2, varscan2
- ESR1 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 200/698 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs745984515, COSV99237340; called by muse, mutect2, varscan2
- EXOC3L1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772773128, COSV52045258; called by muse, mutect2, varscan2
- EXOSC8 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757600036; called by muse, mutect2, varscan2
- EXPH5 | c.4832G>A p.S1611N | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as rs933593785; called by muse, mutect2
- F13A1 | c.869del p.P290Hfs*72 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | catalogued as CM103179, COSV53554649; called by pindel, varscan2
- FABP6 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs17856662, COSV67436666; called by muse, mutect2, varscan2
- FAH | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 103/452 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs755234891, COSV55720695; called by muse, mutect2, varscan2
- FAM131C | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs939398090; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM161B | c.255del p.E86Sfs*35 (on ENST00000651776; = p.E23Sfs*35 on NM_152445.3) | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | catalogued as rs775951198; called by mutect2, pindel, varscan2
- FAM166C | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs767810976, COSV99052108; called by muse, varscan2
- FAM214A | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1268904252; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM220A | c.194T>C p.M65T | Missense Mutation (SNP) | VAF 107/443 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs551687469; called by muse, mutect2, varscan2
- FAM83C | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 114/458 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs375557298; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 156/664 reads (23%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM83H | c.2727del p.E910Sfs*64 | Frame Shift Del (DEL) | VAF 134/682 reads (20%) | catalogued as COSV100567936; called by mutect2, pindel, varscan2
- FASN | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 121/550 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV60754793; called by muse, mutect2, varscan2
- FBH1 | c.2056G>A p.A686T (on ENST00000362091 / NM_178150.3; = p.A737T on NM_032807.4) | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.87); catalogued as rs1319822702, COSV62981687; called by muse, mutect2, varscan2
- FBN2 | c.5588G>A p.R1863Q | Missense Mutation (SNP) | VAF 141/560 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs1447600676; called by muse, mutect2, varscan2
- FBXL4 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766177758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL7 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 80/305 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100309871; called by muse, mutect2, varscan2
- FBXO22 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs958919463, COSV57618114, COSV57619241; called by muse, mutect2, varscan2
- FDXACB1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs191172184; called by muse, mutect2, varscan2
- FFAR2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200165905, COSV55831656; called by muse, mutect2, varscan2
- FITM1 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV52823528; called by muse, mutect2, varscan2
- FLCN | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs752006809, COSV53259578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLII | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs745739120, COSV58947560; called by muse, mutect2, varscan2
- FLRT2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766170020, COSV100420725, COSV58149961; called by muse, mutect2, varscan2
- FMNL3 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773190923, COSV53301582; called by muse, mutect2, varscan2
- FOXJ1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1394240137; called by muse, mutect2, varscan2
- FOXN1 | c.1465dup p.Q489Pfs*40 | Frame Shift Ins (INS) | VAF 15/82 reads (18%) | catalogued as rs1169577591; called by mutect2, pindel, varscan2
- FREM2 | c.8056G>A p.V2686M | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs144935150; called by muse, mutect2, varscan2
- FREM3 | c.5454del p.D1819Tfs*25 | Frame Shift Del (DEL) | VAF 29/184 reads (16%) | catalogued as rs1560848767; called by mutect2, pindel, varscan2
- FREM3 | c.5236G>A p.A1746T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1050229662; called by muse, mutect2, varscan2
- FSCN1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs754863638, COSV61017595; called by muse, mutect2, varscan2
- FSD1L | c.319C>T p.R107C (on ENST00000481272 / NM_001145313.3; = p.R75C on NM_031919.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs200324817; called by muse, mutect2, varscan2
- FURIN | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1246114763; called by muse, mutect2, varscan2
- FZD5 | c.480dup p.R161Qfs*108 | Frame Shift Ins (INS) | VAF 35/155 reads (23%) | catalogued as rs1413162495; called by mutect2, pindel, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GABRG3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1181064418, COSV61509011, COSV61531239; called by muse, mutect2, varscan2
- GADD45B | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53126504; called by muse, mutect2, varscan2
- GADL1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs1257298779; called by muse, mutect2, varscan2
- GAS8 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs765671895; called by muse, mutect2, varscan2
- GBF1 | c.1258G>A p.D420N (on ENST00000369983 / NM_001377137.1; = p.D419N on NM_004193.3) | Missense Mutation (SNP) | VAF 106/443 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs41303829; called by muse, mutect2, varscan2
- GCN1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1341306715, COSV56109840; called by muse, mutect2, varscan2
- GCN1 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs575068347; called by muse, mutect2, varscan2
- GCNT2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764632923; called by muse, mutect2, varscan2
- GDF10 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.102); catalogued as rs376019600; called by muse, mutect2
- GDF7 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV55347940; called by muse, mutect2, varscan2
- GDPD5 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565726247; called by muse, mutect2, varscan2
- GEMIN4 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs368058625; called by muse, mutect2, varscan2
- GFOD1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as rs1188656051, COSV64955027; called by muse, mutect2
- GIGYF1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771986611, COSV51941211; called by muse, varscan2
- GIGYF1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as rs1220831821; called by muse, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 34/267 reads (13%) | catalogued as rs771881138; called by mutect2, varscan2
- GJA1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 123/485 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as CM095018, COSV56997932; called by muse, mutect2, varscan2
- GLT1D1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1056085473; called by muse, mutect2, varscan2
- GLUD1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1050159; called by muse, mutect2, varscan2
- GLYCTK | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs547489088; called by muse, mutect2, varscan2
- GMPPA | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs752124820, COSV100354866; called by muse, mutect2
- GNAS | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 184/698 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV55690068; called by muse, mutect2, varscan2
- GNL3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316204392; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 253/1763 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs1242360337; called by muse, varscan2
- GORASP2 | c.1251del p.T418Lfs*74 | Frame Shift Del (DEL) | VAF 68/320 reads (21%) | catalogued as COSV52202002; called by pindel, varscan2
- GPR143 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309522047, COSV101102189; called by muse, mutect2, varscan2
- GPR26 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.865); catalogued as COSV52936362; called by muse, mutect2, varscan2
- GPR45 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1014931172, COSV51523771; called by muse, mutect2, varscan2
- GPR61 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 61/216 reads (28%) | catalogued as COSV68177448; called by muse, mutect2, varscan2
- GRIFIN | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs766790997; called by muse, mutect2, varscan2
- GRK1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 138/659 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as rs372559555; called by muse, mutect2, varscan2
- GRM6 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51432798; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | catalogued as COSV58842099; called by mutect2, varscan2
- GSDME | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 123/500 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as rs139931428; called by muse, mutect2, varscan2
- H2BC4 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs748963266, COSV58416857; called by muse, mutect2, varscan2
- H2BW2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1482998729, COSV99685859, COSV99685922; called by muse, mutect2
- H3-4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as rs756810829; called by muse, mutect2, varscan2
- HCN1 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 156/732 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57501369, COSV57539260; called by muse, varscan2
- HDAC4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as rs766581830, COSV61871658; called by muse, mutect2
- HDHD2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200669234; called by mutect2, varscan2
- HDHD2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs142900978, COSV56075290; called by muse, mutect2, varscan2
- HECTD4 | c.6626C>T p.A2209V | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV66387705; called by muse, mutect2, varscan2
- HECTD4 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs552220692; called by muse, mutect2, varscan2
- HELQ | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as rs748050831, COSV55024306; called by muse, mutect2, varscan2
- HEYL | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs368236989; called by muse, mutect2, varscan2
- HHLA1 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 111/351 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1001027644; called by muse, mutect2, varscan2
- HIC2 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101335591, COSV68041728; called by muse, mutect2
- HIP1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 79/306 reads (26%) | catalogued as rs1247000628, COSV100417796; called by muse, mutect2, varscan2
- HIP1 | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100417174; called by muse, mutect2, varscan2
- HMCN2 | c.9197C>T p.A3066V | Missense Mutation (SNP) | VAF 108/438 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs1052451359, COSV101508804; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXC13 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 160/556 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498075; called by muse, mutect2, varscan2
- HP | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs768960704; called by muse, mutect2, varscan2
- HSPG2 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 121/489 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs532799636; called by muse, mutect2, varscan2
- HTR3C | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs138533542, COSV59175400; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | catalogued as rs779457274; called by mutect2, varscan2
- IDH2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 122/448 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51564478; called by muse, mutect2, varscan2
- IDO2 | c.302C>T p.A101V (on ENST00000389060; = p.A114V on NM_194294.2) | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1249765602, COSV100584888; called by muse, mutect2, varscan2
- IFI35 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs977580584; called by muse, mutect2, varscan2
- IFIT1B | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs745323238; called by muse, mutect2, varscan2
- IFRD2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs782601507, COSV57115664; called by muse, mutect2, varscan2
- IFT140 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs757678246; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 67/346 reads (19%) | catalogued as rs760021495; called by mutect2, varscan2
- IGLV3-1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 132/608 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs137930227; called by muse, mutect2, varscan2
- IL20RA | c.1271_1273del p.E424del | In Frame Del (DEL) | VAF 60/258 reads (23%) | catalogued as rs757830334; called by pindel, varscan2
- IL24 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs771354331; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 92/400 reads (23%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IMPDH2 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58247209; called by muse, mutect2, varscan2
- INSL3 | c.148del p.R50Afs*77 | Frame Shift Del (DEL) | VAF 61/336 reads (18%) | catalogued as rs1187807999, COSV57952815; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INTS10 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs201728325; called by muse, varscan2
- INTS14 | c.1288dup p.T430Nfs*6 (on ENST00000313182 / NM_001366360.2; = p.T351Nfs*6 on NM_001136043.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/112 reads (20%) | catalogued as rs781635472; called by mutect2, pindel, varscan2
- IQSEC1 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 106/441 reads (24%) | catalogued as rs1332327407; called by muse, mutect2, varscan2
- IRF9 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 73/418 reads (17%) | catalogued as COSV60703061; called by muse, mutect2, varscan2
- ISL2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV51959183; called by muse, mutect2, varscan2
- ITGA8 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1010582317, COSV65237294; called by muse, mutect2, varscan2
- ITGA9 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 159/653 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1160031026; called by muse, mutect2, varscan2
- ITGAV | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs751267868; called by muse, mutect2, varscan2
- ITGB3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs760480847, COSV71383470; called by muse, mutect2, varscan2
- ITGB4 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 95/406 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536954831; called by muse, mutect2, varscan2
- ITIH2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377268702; called by muse, mutect2
- ITPR1 | c.4756C>T p.R1586C (on ENST00000354582; = p.R1571C on NM_002222.7) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs373619512, COSV100231723; called by muse, mutect2, varscan2
- ITPR3 | c.2563_2565del p.E855del | In Frame Del (DEL) | VAF 27/144 reads (19%) | catalogued as rs754177801; called by pindel, varscan2
- JCAD | c.2927C>T p.T976M | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs756349116; called by muse, mutect2, varscan2
- JMJD6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.254); catalogued as rs1163022715; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 133/573 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760597072, COSV59826591; called by muse, mutect2, varscan2
- JPH2 | c.62del p.G21Efs*54 | Frame Shift Del (DEL) | VAF 34/267 reads (13%) | catalogued as rs1206579645; called by mutect2, pindel, varscan2
- JSRP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV55555737; called by muse, mutect2, varscan2
- KALRN | c.5683C>T p.R1895W (on ENST00000360013 / NM_001024660.4; = p.R198W on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs150257895, COSV52251688; called by muse, mutect2
- KCNA4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100069192, COSV60254086; called by muse, mutect2, varscan2
- KCNAB3 | c.697del p.A233Lfs*16 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs745672481; called by mutect2, pindel, varscan2
- KCNG1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 166/758 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022678362; called by muse, mutect2, varscan2
- KCNG3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs564466098; called by muse, mutect2, varscan2
- KCNH5 | c.11del p.G4Afs*37 | Frame Shift Del (DEL) | VAF 47/256 reads (18%) | catalogued as COSV59765016; called by mutect2, pindel, varscan2
- KCNJ14 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992971743; called by muse, mutect2, varscan2
- KCNJ8 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 32/155 reads (21%) | catalogued as COSV53716291; called by muse, mutect2, varscan2
- KCNN2 | c.559G>A p.V187M (on ENST00000264773; = p.V399M on NM_021614.4) | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV99299748; called by muse, mutect2, varscan2
- KCNS3 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs775574102, COSV58406156; called by muse, mutect2, varscan2
- KDM2B | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV100997401; called by muse, mutect2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 65/265 reads (25%) | catalogued as rs1561792565; called by mutect2, varscan2
- KHDRBS2 | c.668del p.P223Lfs*6 | Frame Shift Del (DEL) | VAF 39/178 reads (22%) | catalogued as COSV55452564, COSV99028884; called by mutect2, pindel, varscan2
- KHK | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 109/450 reads (24%) | catalogued as COSV53157764; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 44/176 reads (25%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA2012 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1338742487; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIF26A | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 216/800 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs376020927; called by muse, mutect2, varscan2
- KIF26B | c.2660del p.P887Qfs*35 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | catalogued as rs1208357637; called by mutect2, pindel, varscan2
- KIF7 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs1394292136; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 33/161 reads (20%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL26 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 31/373 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1297490717; called by muse, mutect2
- KLHL30 | c.870del p.G291Afs*34 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs1559275279; called by mutect2, pindel, varscan2
- KLHL42 | c.1194dup p.C399Vfs*43 | Frame Shift Ins (INS) | VAF 11/80 reads (14%) | catalogued as rs749194179; called by mutect2, varscan2
- KLK8 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs747062903, COSV51593277; called by muse, mutect2, varscan2
- KLKB1 | c.418dup p.R140Kfs*5 | Frame Shift Ins (INS) | VAF 100/319 reads (31%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KMT2C | c.5716C>T p.R1906* | Nonsense Mutation (SNP) | VAF 37/188 reads (20%) | catalogued as rs763438739, COSV51279719, COSV51462477; called by muse, mutect2, varscan2
- KPTN | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1425926253; called by muse, mutect2, varscan2
- KRT12 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs779768900, COSV52432616; called by muse, mutect2, varscan2
- KRT38 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs760012734; called by muse, mutect2, varscan2
- L1TD1 | c.1517A>G p.Q506R | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1366393767; called by muse, mutect2, varscan2
- LAMA2 | c.4825C>A p.L1609M | Missense Mutation (SNP) | VAF 63/415 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV70350725; called by muse, mutect2, varscan2
- LAMA5 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53372673; called by muse, mutect2, varscan2
- LAMB1 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 109/506 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs547247575, COSV55970311; called by muse, mutect2, varscan2
- LANCL3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV101065413; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LARP1 | c.2351G>A p.R784H (on ENST00000518297 / NM_033551.3; = p.R707H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/665 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs766791311, COSV60429251; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 35/130 reads (27%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGALS3BP | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99431949; called by muse, mutect2, varscan2
- LINGO3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs1343054102; called by muse, mutect2, varscan2
- LLGL2 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs754867865; called by muse, mutect2, varscan2
- LMAN1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs751738490, COSV51829099; called by muse, varscan2
- LPP | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs748763447; called by muse, mutect2, varscan2
- LRCH3 | c.1962_1964del p.E655del | In Frame Del (DEL) | VAF 29/125 reads (23%) | catalogued as rs759920668; called by pindel, varscan2
- LRFN1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.679); catalogued as rs1166129592; called by muse, mutect2, varscan2
- LRFN1 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.362); catalogued as COSV50451647; called by muse, mutect2, varscan2
- LRP1 | c.13553G>A p.R4518H | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751094440; called by muse, mutect2, varscan2
- LRP1B | c.5003C>T p.S1668L | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.761); catalogued as COSV67220590; called by muse, mutect2
- LRPPRC | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as rs746496250; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRK1 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 88/293 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1015630432, COSV52608388; called by muse, mutect2, varscan2
- LRRTM1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV54448413; called by muse, mutect2, varscan2
- LSM14B | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1277110925; called by muse, mutect2, varscan2
- LTBP1 | c.231del p.V79Sfs*143 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs1215027021; called by mutect2, pindel, varscan2
- LTBP3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 138/542 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs1161239982; called by muse, mutect2, varscan2
- LYST | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | catalogued as rs1412672912, COSV67713807; called by muse, mutect2, varscan2
- MAB21L1 | c.734del p.G245Afs*13 | Frame Shift Del (DEL) | VAF 22/181 reads (12%) | catalogued as rs1489102829, COSV100076702; called by mutect2, pindel, varscan2
- MAGEB17 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1388945346; called by muse, varscan2
- MAGED2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as rs867098630, COSV54497627; called by muse, mutect2, varscan2
- MAGEE1 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 107/432 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs782712878; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGEH1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 63/290 reads (22%) | catalogued as COSV61679082; called by muse, mutect2, varscan2
- MAGI2 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753587569; called by muse, varscan2
- MAMDC2 | c.1842_1844del p.R616del | In Frame Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs1261530697; called by pindel, varscan2
- MAML1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs760412182; called by muse, mutect2, varscan2
- MAML2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101594066; called by muse, mutect2, varscan2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | catalogued as COSV55811343; called by pindel, varscan2
- MAP4K1 | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as COSV101204137; called by muse, mutect2, varscan2
- MAPK4 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs767125390, COSV101245429; called by muse, mutect2, varscan2
- MARCO | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV59055942; called by muse, mutect2, varscan2
- MCF2L | c.487G>A p.V163I (on ENST00000375608; = p.V131I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as rs763446044, COSV65052183; called by muse, mutect2, varscan2
- MCTP1 | c.1592_1594del p.G531del | In Frame Del (DEL) | VAF 66/311 reads (21%) | catalogued as rs749032818; called by pindel, varscan2
- MDFI | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.144); catalogued as COSV100025599, COSV57822239; called by muse, mutect2, varscan2
- MDGA2 | c.1961C>T p.T654M (on ENST00000399232 / NM_001113498.2; = p.T356M on NM_182830.4) | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs758142772, COSV62081973; called by muse, mutect2, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/162 reads (27%) | catalogued as COSV99487865; called by mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 46/287 reads (16%) | catalogued as rs759225724, COSV53895347; called by mutect2, varscan2
- MEGF8 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as COSV52083190; called by muse, mutect2, varscan2
- MESD | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV55725165; called by muse, mutect2, varscan2
- MEX3D | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 92/318 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1163526597, COSV66312420; called by muse, mutect2, varscan2
- MEX3D | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 127/456 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs771190527, COSV66311958; called by muse, mutect2, varscan2
- MFSD10 | c.745del p.L249Wfs*29 | Frame Shift Del (DEL) | VAF 61/254 reads (24%) | catalogued as COSV99296832; called by mutect2, pindel, varscan2
- MGAT4B | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs748599210, COSV99482053; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 25/170 reads (15%) | catalogued as rs751944867; called by mutect2, varscan2
- MIDEAS | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs751958957; called by muse, varscan2
- MIGA1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs772067225, COSV66223452; called by muse, varscan2
- MLF1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as rs141212572; called by muse, mutect2, varscan2
- MLLT1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs748081218, COSV99397844; called by muse, varscan2
- MLXIPL | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 128/508 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as rs782092916, COSV57668767; called by muse, varscan2
- MLXIPL | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 133/530 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs782150923; called by muse, mutect2, varscan2
- MMD2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.028); catalogued as rs948008887, COSV68660649; called by muse, mutect2, varscan2
- MMP21 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.903); catalogued as rs372562000; called by muse, mutect2, varscan2
- MMP8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs563802778; called by muse, varscan2
- MON2 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as rs1003008908; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRAP | c.107-5C>T | Splice Region (SNP) | VAF 125/526 reads (24%) | catalogued as rs373512270; called by muse, mutect2, varscan2
- MRGPRX3 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs781690794, COSV66934882; called by muse, mutect2
- MSRB1 | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 122/497 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs770241137, COSV99238062; called by muse, mutect2, varscan2
- MSX1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs902284125, COSV66947773; called by muse, mutect2, varscan2
- MTCL1 | c.4714del p.A1572Hfs*28 (on ENST00000306329 / NM_001378206.1; = p.A1253Hfs*28 on NM_015210.4) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1209504789; called by mutect2, pindel, varscan2
- MTHFSD | c.728G>A p.R243H (on ENST00000360900 / NM_001159377.2; = p.R242H on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs755482028; called by muse, varscan2
- MTMR3 | c.2349del p.R784Gfs*15 | Frame Shift Del (DEL) | VAF 49/332 reads (15%) | catalogued as COSV100070564; called by mutect2, varscan2
- MTUS2 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200465559, COSV99079522; called by muse, mutect2, varscan2
- MUC16 | c.29203C>A p.L9735I | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.263); catalogued as rs755909314; called by muse, mutect2, varscan2
- MUC5B | c.5825C>T p.T1942M | Missense Mutation (SNP) | VAF 160/632 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs752678107, COSV71594918; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 51/234 reads (22%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPHL | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs199935853; called by muse, mutect2
- MYH10 | c.5536C>T p.R1846C | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763285249, COSV99345450; called by muse, mutect2, varscan2
- MYH2 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 138/525 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745807547, COSV55431734; called by muse, mutect2, varscan2
- MYH9 | c.3249G>T p.E1083D | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV53387066; called by muse, mutect2, varscan2
- MYO10 | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs368821991; called by muse, mutect2, varscan2
- MYO15A | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs757868524; called by muse, mutect2, varscan2
- MYO18A | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV104416421; called by muse, mutect2, varscan2
- MYO19 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557418507; called by muse, mutect2, varscan2
- MYOCD | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58515032; called by muse, mutect2, varscan2
- MYORG | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339571925; called by muse, mutect2, varscan2
- MYOZ3 | c.412del p.A138Pfs*10 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as COSV99770842; called by mutect2, pindel
- MYRFL | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1350428845; called by muse, mutect2, varscan2
- MYSM1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747437450, COSV101284065; called by muse, mutect2, varscan2
- MYT1L | c.382del p.D128Tfs*46 | Frame Shift Del (DEL) | VAF 76/336 reads (23%) | catalogued as COSV67730728; called by mutect2, pindel, varscan2
- NAALADL2 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101380516; called by muse, mutect2, varscan2
- NBEA | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59762766; called by muse, mutect2, varscan2
- NBPF11 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 148/745 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as rs1221652597; called by muse, mutect2, varscan2
- NCF4 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs369847561, COSV50627198; ClinVar: uncertain significance; called by muse, mutect2
- NCKAP1 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV62939711; called by mutect2, varscan2
- NCKAP1L | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756906173, COSV53204504, COSV53210746; called by muse, mutect2, varscan2
- NDRG2 | c.467C>T p.A156V (on ENST00000298687 / NM_001354570.1; = p.A142V on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/438 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1216275980; called by muse, mutect2, varscan2
- NDST2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1249833803, COSV100013765, COSV55212916; called by muse, mutect2, varscan2
- NDUFS8 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1282276522; called by muse, mutect2, varscan2
- NDUFV1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs759807863; called by muse, mutect2, varscan2
- NEB | c.13756C>T p.R4586C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs374606967; ClinVar: uncertain significance; called by muse, varscan2
- NEDD4 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100163310; called by muse, mutect2, varscan2
- NEURL1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201516316; called by muse, mutect2, varscan2
- NFASC | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs370138600; called by muse, mutect2, varscan2
- NFATC2 | c.419del p.P140Rfs*28 | Frame Shift Del (DEL) | VAF 51/239 reads (21%) | catalogued as COSV101044898; called by mutect2, pindel, varscan2
- NFIA | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as rs751696907, COSV64533596; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 88/442 reads (20%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIN | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1348032914, COSV55381045; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs767007251; called by mutect2, varscan2
- NKX2-6 | c.30del p.F11Sfs*34 | Frame Shift Del (DEL) | VAF 19/155 reads (12%) | catalogued as COSV100273957; called by mutect2, pindel, varscan2
- NLE1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745418741, COSV62604060; called by muse, mutect2, varscan2
- NLRP14 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 51/268 reads (19%) | catalogued as COSV55069500; called by muse, varscan2
- NLRP2 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs144271525; called by muse, mutect2, varscan2
- NOL4 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 42/140 reads (30%) | catalogued as COSV52347042; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL8 | c.418-8del | Splice Region (DEL) | VAF 38/106 reads (36%) | catalogued as rs756440973; called by mutect2, varscan2
- NPHP1 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as CM066933; called by muse, mutect2, varscan2
- NPHP4 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs369624442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPIPB15 | c.1283del p.K428Rfs*? | Frame Shift Del (DEL) | VAF 70/750 reads (9%) | catalogued as rs1567419461; called by pindel, varscan2
- NPM2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57075073; called by muse, mutect2, varscan2
- NPNT | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs899234227, COSV59755820; called by muse, mutect2, varscan2
- NPRL3 | c.1162-5C>T | Splice Region (SNP) | VAF 49/232 reads (21%) | catalogued as rs768868339; called by muse, mutect2, varscan2
- NR1H2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as rs1349280396; called by muse, mutect2, varscan2
- NR3C1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs748311337; called by muse, mutect2
- NRN1L | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 204/773 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs745469040; called by muse, mutect2, varscan2
- NSG1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758849842, COSV60373572; called by muse, mutect2, varscan2
- NSMF | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 88/565 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs1038133430, COSV52993979; called by muse, mutect2, varscan2
- NSRP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs572953048, COSV55936160; called by muse, mutect2, varscan2
- NSUN2 | c.1797_1798del p.A600Ffs*16 | Frame Shift Del (DEL) | VAF 50/298 reads (17%) | catalogued as rs1394056446; called by pindel, varscan2
- NTN3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs765907721; called by muse, mutect2, varscan2
- NUAK2 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780926337, COSV100904057, COSV100904097; called by muse, mutect2, varscan2
- NUDT18 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1270855846; called by muse, mutect2, varscan2
- NUDT3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101466190; called by muse, mutect2, varscan2
- NUDT5 | c.266del p.G89Afs*4 | Frame Shift Del (DEL) | VAF 47/219 reads (21%) | catalogued as rs1564424334; called by mutect2, varscan2
- NUTM2D | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1318081966; called by mutect2, varscan2
- NUTM2F | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs767026006; called by muse, mutect2, varscan2
- NXN | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 78/569 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200704586; called by muse, mutect2
- NXPE2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV64940726; called by muse, mutect2, varscan2
- NXPH4 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 134/577 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs865982196; called by muse, mutect2, varscan2
- OBSCN | c.5648G>A p.R1883H | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as rs765855953, COSV52819912; called by muse, mutect2, varscan2
- OBSCN | c.5728G>A p.A1910T | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as rs574126820; called by muse, mutect2, varscan2
- OBSCN | c.6589C>T p.R2197C | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs868640041, COSV99472215; called by muse, mutect2, varscan2
- OBSCN | c.9869C>T p.T3290M | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs201902729; called by muse, mutect2, varscan2
- OGDHL | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266279200; called by muse, mutect2
- OMP | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs373946879; called by muse, mutect2
- OPN4 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs775728827, COSV54118171; called by muse, mutect2, varscan2
- OR10G7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs779903828, COSV57869277; called by muse, mutect2, varscan2
- OR1J4 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs759858630; called by muse, mutect2, varscan2
- OR2M3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV101513415; called by muse, mutect2, varscan2
- OR4C15 | c.328T>C p.S110P (on ENST00000314644; = p.S56P on NM_001001920.2) | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1250653132; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 160/378 reads (42%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52R1 | c.663del p.Y221* | Frame Shift Del (DEL) | VAF 64/286 reads (22%) | catalogued as COSV61889447; called by mutect2, pindel, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | catalogued as rs201077183; called by mutect2, varscan2
- OR8D1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as COSV63442776; called by muse, mutect2
- OSBP2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60241264; called by muse, mutect2, varscan2
- OTOS | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs370264573; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 72/282 reads (26%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- OXNAD1 | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99551013; called by muse, mutect2, varscan2
- P3H2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs865964864; called by muse, mutect2, varscan2
- PAFAH2 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959210; called by muse, mutect2
- PARD6G | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 152/604 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62061070; called by muse, mutect2, varscan2
- PARP14 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs745695997; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 15/100 reads (15%) | catalogued as rs757903860; called by mutect2, varscan2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH17 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1485429803; called by muse, mutect2, varscan2
- PCDH7 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 75/286 reads (26%) | catalogued as COSV62336392; called by muse, mutect2, varscan2
- PCDHA1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs149577981, COSV65374522; called by muse, mutect2, varscan2
- PCDHA12 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 220/843 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs1554169178, COSV100248065; called by muse, mutect2, varscan2
- PCDHA3 | c.596dup p.N199Kfs*9 | Frame Shift Ins (INS) | VAF 40/178 reads (22%) | catalogued as rs782411180; called by mutect2, varscan2
- PCDHB11 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554285419, COSV61312176; called by muse, mutect2, varscan2
- PCDHB5 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 196/819 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs140704539; called by muse, mutect2, varscan2
- PCDHB6 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.74); catalogued as rs562020652; called by muse, mutect2
- PCDHGA5 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs1234948467, COSV54017918; called by muse, mutect2
- PCDHGB5 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs774561101, COSV53930506; called by muse, mutect2, varscan2
- PCDHGC4 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 100/345 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs769661146; called by muse, mutect2, varscan2
- PCNT | c.3469G>A p.A1157T | Missense Mutation (SNP) | VAF 108/513 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); catalogued as rs778900170, COSV64025671; called by muse, mutect2, varscan2
- PCSK6 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754908777; called by muse, mutect2, varscan2
- PDE4DIP | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 70/722 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371331495; called by muse, mutect2
- PDILT | c.680del p.K227Rfs*5 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | catalogued as rs745333926; called by mutect2, pindel, varscan2
- PDZD2 | c.6733C>T p.R2245C | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs768642055, COSV56869983; called by muse, mutect2, varscan2
- PEG3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146466276; called by muse, mutect2, varscan2
- PEX10 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs756537855, COSV99992257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX11G | c.723del p.*242Dfs*37 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as COSV55537361; called by mutect2, pindel, varscan2
- PEX13 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs766710343; called by muse, mutect2, varscan2
- PEX5L | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV55844949, COSV55860300; called by muse, mutect2, varscan2
- PFKP | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1280636156; called by muse, mutect2, varscan2
- PGC | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1187092869, COSV57823435; called by muse, mutect2, varscan2
- PHEX | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 131/524 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs768400503, COSV101039549, COSV65078293; called by muse, mutect2, varscan2
- PHF20L1 | c.965dup p.N322Kfs*2 | Frame Shift Ins (INS) | VAF 28/128 reads (22%) | catalogued as rs755467695; called by mutect2, varscan2
- PHKA2 | c.3391G>C p.V1131L | Missense Mutation (SNP) | VAF 119/394 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV66056776; called by muse, mutect2, varscan2
- PHLPP1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs539746714; called by muse, mutect2, varscan2
- PHLPP1 | c.3251G>A p.R1084H | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs780394677, COSV53034405, COSV99408908; called by muse, mutect2, varscan2
- PHLPP2 | c.3403_3405del p.S1135del | In Frame Del (DEL) | VAF 64/318 reads (20%) | catalogued as rs747144814; called by pindel, varscan2
- PHLPP2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1394778309, COSV62424175; called by muse, mutect2, varscan2
- PHRF1 | c.2009C>T p.A670V (on ENST00000264555 / NM_001286581.2; = p.A669V on NM_020901.4) | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs778725659; called by muse, mutect2, varscan2
- PIAS4 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99518808; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 12/54 reads (22%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PIK3C2B | c.3727G>A p.V1243I | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100915964; called by muse, mutect2, varscan2
- PIWIL3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV59994393; called by muse, mutect2, varscan2
- PKD2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs549787080, COSV52936241, COSV52941197; called by muse, mutect2, varscan2
- PKDREJ | c.3364G>T p.G1122C | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53548795; called by muse, mutect2, varscan2
- PKM | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 124/631 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751885485, COSV58790471; called by muse, mutect2, varscan2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- PLEKHA8 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 89/392 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs950425344, COSV99321287; called by muse, mutect2, varscan2
- PLEKHG4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs766255385; called by muse, mutect2, varscan2
- PLEKHM2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1331611746; called by muse, mutect2, varscan2
- PLPP7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776448456; called by muse, mutect2, varscan2
- PLS3 | c.396G>C p.W132C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99171705; called by muse, varscan2
- PLXDC1 | c.593-9_593-7del | Splice Region (DEL) | VAF 38/270 reads (14%) | catalogued as rs755630405; called by pindel, varscan2
- PLXNA3 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.487); catalogued as COSV100860093; called by muse, mutect2, varscan2
- PLXNB1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 62/301 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs760134829, COSV56487196; called by muse, mutect2, varscan2
- PNCK | c.633dup p.F212Lfs*8 (on ENST00000340888 / NM_001366975.1; = p.F295Lfs*8 on NM_001039582.3) | Frame Shift Ins (INS) | VAF 38/188 reads (20%) | catalogued as rs781891121; called by mutect2, varscan2
- PNMA8B | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs1401680037; called by muse, mutect2, varscan2
- POLR1A | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs546896040, COSV55701073; called by muse, mutect2, varscan2
- POLR1D | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1014369151, CM108857, COSV57256177; called by muse, mutect2, varscan2
- POLRMT | c.2766C>T p.D922= | Splice Region (SNP) | VAF 54/170 reads (32%) | catalogued as rs757311750; called by muse, mutect2, varscan2
- POSTN | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771376752, COSV65712815; called by muse, mutect2, varscan2
- POU3F3 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1207426311; called by muse, varscan2
- PPFIA2 | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470742734, COSV61033523; called by muse, mutect2, varscan2
- PPFIBP2 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs576520973; called by muse, mutect2
- PPP1R14A | c.87del p.L30Cfs*54 | Frame Shift Del (DEL) | VAF 79/330 reads (24%) | catalogued as rs751874633; called by mutect2, pindel, varscan2
- PPP1R3A | c.2823G>T p.M941I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs376809464, COSV52883656; called by muse, mutect2
- PPP1R3C | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1415699605, COSV53289312; called by muse, mutect2, varscan2
- PPP1R3D | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.245); catalogued as rs746541345; called by muse, varscan2
- PPP1R3G | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV68161106; called by muse, mutect2, varscan2
- PPP2R5D | c.1261C>A p.R421S | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934509389; called by muse, mutect2, varscan2
- PPRC1 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1171066198; called by muse, mutect2, varscan2
- PRDM10 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs141679521; called by muse, mutect2, varscan2
- PRDM16 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs201912252; called by muse, mutect2, varscan2
- PRDM6 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs1257049339; called by muse, mutect2, varscan2
- PRKACA | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431772; called by muse, mutect2, varscan2
- PRKCG | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758442836; called by muse, mutect2, varscan2
- PRLR | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs781305716, COSV99184419; called by muse, mutect2, varscan2
- PROS1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD951837; called by muse, mutect2, varscan2
- PRPF40A | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV68359595; called by muse, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 100/194 reads (52%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR35 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs751729638; called by muse, mutect2, varscan2
- PRSS56 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1227274904; called by muse, mutect2, varscan2
- PSAP | c.556del p.R186Afs*20 | Frame Shift Del (DEL) | VAF 55/247 reads (22%) | catalogued as COSV67551246; called by mutect2, pindel, varscan2
- PSD3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.691); catalogued as rs926362251; called by muse, mutect2, varscan2
- PSG6 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs769630585; called by muse, mutect2, varscan2
- PSMD2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 43/218 reads (20%) | catalogued as rs1489238012; called by muse, mutect2, varscan2
- PSME1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs146188494; called by muse, varscan2
- PTPRJ | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs778048790, COSV69253016; called by muse, varscan2
- PTPRS | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53610456; called by muse, mutect2, varscan2
- PTPRU | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380386412; called by muse, mutect2, varscan2
- PWP1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs538198996, COSV69832378, COSV69832976; called by muse, mutect2, varscan2
- PWWP3B | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1569368779, COSV100531673; called by muse, mutect2, varscan2
- PXDN | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs749632473; called by muse, mutect2, varscan2
- PXDNL | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62481105; called by muse, mutect2
- PXN | c.1591C>T p.R531C (on ENST00000228307 / NM_001080855.3; = p.R497C on NM_002859.4) | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1325851694; called by muse, mutect2, varscan2
- PYDC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs377601641; called by muse, mutect2, varscan2
- PYHIN1 | c.423dup p.P142Tfs*3 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | catalogued as rs758393003; called by mutect2, varscan2
- PYROXD2 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1467855177, COSV65330342; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as rs375424635; called by muse, mutect2, varscan2
- RAB11FIP4 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1359923820; called by muse, mutect2, varscan2
- RAB11FIP5 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs912737985, COSV50256691; called by muse, mutect2, varscan2
- RACK1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59318629; called by muse, varscan2
- RAG1 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753962790; called by muse, mutect2, varscan2
- RAI1 | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 26/455 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55395852; called by muse, mutect2
- RANBP9 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs780793088, COSV50580211; called by muse, mutect2, varscan2
- RAPSN | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 110/540 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753956536; called by muse, mutect2, varscan2
- RASA3 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863639; called by muse, mutect2, varscan2
- RBBP6 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1351169090; called by muse, mutect2
- RBM4B | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as rs776465986; called by muse, mutect2, varscan2
- REC8 | c.827del p.P276Rfs*142 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs766853930; called by mutect2, varscan2
- RERE | c.3808C>T p.R1270C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs368654266; called by muse, mutect2, varscan2
- RESF1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs754040228; called by muse, mutect2, varscan2
- REV3L | c.4873del p.S1625Qfs*28 | Frame Shift Del (DEL) | VAF 12/119 reads (10%) | catalogued as rs1381009149; called by mutect2, pindel, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS19 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755556137; called by muse, mutect2, varscan2
- RIC8B | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62694660; called by muse, mutect2, varscan2
- RMC1 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52570821; called by muse, mutect2, varscan2
- RNF112 | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV71327067; called by muse, mutect2, varscan2
- RNF115 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs186281231, COSV65165090; called by muse, mutect2, varscan2
- RNF187 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1201648729, COSV59959895; called by muse, mutect2, varscan2
- RNF213 | c.12860G>A p.R4287Q | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs200034624, COSV60403772; called by muse, mutect2, varscan2
- RNF216 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1314779582, COSV66292442; called by muse, mutect2, varscan2
- ROGDI | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs146815588; called by muse, mutect2, varscan2
- RPE65 | c.597T>A p.N199K | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs141527042, COSV52014131; called by muse, mutect2, varscan2
- RPN1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1356368738; called by muse, mutect2, varscan2
- RPS6KA2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1223838046, COSV55816243; called by muse, mutect2
- RRM1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs772263282; called by muse, mutect2, varscan2
- RRP1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs1428445931, COSV71856992; called by muse, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RXFP3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs769933125; called by muse, mutect2, varscan2
- RYR1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs748318655, COSV100615705, COSV62107125; called by muse, mutect2, varscan2
- RYR3 | c.5279C>T p.A1760V | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs777812122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.12301G>A p.A4101T | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV66533860; called by muse, mutect2
- SACS | c.11886A>G p.I3962M | Missense Mutation (SNP) | VAF 123/445 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs1252737332; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 68/634 reads (11%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SBNO2 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as rs554702050; called by muse, mutect2, varscan2
- SBNO2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs373976043; called by muse, varscan2
- SCAF4 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1450213621; called by muse, mutect2, varscan2
- SCN5A | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as rs199473067, CM100635; ClinVar: not provided; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs751191303; called by mutect2, varscan2
- SELENOO | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 149/611 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749302718; called by muse, mutect2, varscan2
- SERINC5 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs756068379; called by muse, mutect2, varscan2
- SERPINC1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 131/321 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs774294043, COSV100875032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERTAD4 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV65399906; called by muse, mutect2, varscan2
- SETD1B | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1420032279; called by muse, mutect2, varscan2
- SETX | c.5243dup p.L1750Ffs*8 | Frame Shift Ins (INS) | VAF 54/212 reads (25%) | catalogued as rs754706851; called by mutect2, varscan2
- SFRP4 | c.792-4del | Splice Region (DEL) | VAF 8/40 reads (20%) | catalogued as rs745763643; called by mutect2, varscan2
- SFRP5 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 44/240 reads (18%) | catalogued as rs139922168; called by muse, mutect2, varscan2
- SGTB | c.684G>A p.A228= | Splice Region (SNP) | VAF 30/160 reads (19%) | catalogued as rs563437922; called by muse, mutect2, varscan2
- SH2B3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1242525317; called by muse, mutect2, varscan2
- SH3GLB2 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as rs771032182; called by muse, mutect2, varscan2
- SH3TC1 | c.1645dup p.A549Gfs*36 | Frame Shift Ins (INS) | VAF 28/130 reads (22%) | catalogued as rs767017352; called by mutect2, pindel, varscan2
- SHPRH | c.1987T>C p.C663R | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51612776; called by muse, mutect2, varscan2
- SIGLEC1 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.836); catalogued as rs373105785; called by muse, mutect2, varscan2
- SIGLECL1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100324041; called by muse, mutect2, varscan2
- SIN3A | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs369396162, COSV64584076; called by muse, mutect2, varscan2
- SIRT4 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201108193; called by muse, mutect2, varscan2
- SIRT6 | c.80del p.P27Rfs*133 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | catalogued as rs766524945, COSV59446625; called by mutect2, pindel, varscan2
- SLC10A3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs782431405, COSV54836362; called by muse, mutect2, varscan2
- SLC12A2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763775784; called by muse, mutect2, varscan2
- SLC12A7 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs201832498; called by muse, mutect2, varscan2
- SLC1A7 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs749367429; called by muse, mutect2, varscan2
- SLC24A5 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1312635224, COSV58316551; called by muse, mutect2, varscan2
- SLC26A4 | c.-3-3C>T | Splice Region (SNP) | VAF 112/485 reads (23%) | catalogued as rs1449236675; called by muse, mutect2, varscan2
- SLC27A3 | c.1562G>A p.G521D (on ENST00000271857; = p.G393D on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs910853740; called by muse, mutect2, varscan2
- SLC28A1 | c.1581C>T p.S527= | Splice Region (SNP) | VAF 43/160 reads (27%) | catalogued as rs775666799; called by muse, mutect2
- SLC2A4 | c.1326+12del | Splice Region (DEL) | VAF 14/74 reads (19%) | catalogued as rs750600733; called by mutect2, pindel
- SLC30A3 | c.1159del p.Q387Kfs*78 | Frame Shift Del (DEL) | VAF 46/220 reads (21%) | catalogued as rs747206800; called by mutect2, varscan2
- SLC35B2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV51491116; called by muse, mutect2, varscan2
- SLC35D3 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1415362911, COSV59378490; called by muse, mutect2, varscan2
- SLC44A4 | c.618C>T p.S206= | Splice Region (SNP) | VAF 24/204 reads (12%) | catalogued as rs1011482243; called by muse, varscan2
- SLC4A11 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs752287261, CM081815, COSV66261292; ClinVar: uncertain significance; called by muse, mutect2
- SLC52A2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs797045202, COSV57352149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC52A3 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs781769616, COSV99447637; called by muse, mutect2, varscan2
1,813 further variants in this file (967 protein-altering or splice-affecting, 518 silent, 328 other) are not listed here.
